Gene-level copy-number profile of tumor specimen TCGA-2L-AAQJ-01A from TCGA case TCGA-2L-AAQJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.6 years (18,103 days).
Specimen TCGA-2L-AAQJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.5ab8db8b-4edf-45bb-9a45-b3b451407db8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2L-AAQJ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/013e5d0a-435e-4091-9a45-dafb7f98d9b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,652; copy number 2: 47,714; copy number 3: 2,198; copy number 4: 54; copy number 5: 140; copy number 6: 45; copy number 10: 13; copy number 14: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2L-AAQJ-01A-12D-A396-01): tumor purity 0.47, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 201 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:36,948,954–37,479,725, 15 genes, copy number 5 (within-gene range 3–5): AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2.
- chr17:43,395,993–45,608,918, 125 genes, copy number 5 (broad region; genes not listed).
- chr20:20,052,514–20,360,703, 1 gene, copy number 10 (within-gene range 1–14): CFAP61.
- chr20:20,214,299–23,132,635, 60 genes, copy number 6–14: AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656.

Autosomal genes at a single copy (total copy number 1): 9,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
